Surgical pathology report (de-identified scan), TCGA case TCGA-XK-AAIV, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site Mayo Clinic Arizona, specimen TCGA-XK-AAIV-01A (Primary Tumor).

[page 1 of 4]
Clinical Notes Report
-Surgical Pathology Report -

Result Type: Surgical Pathology Report

Result Date:

Performed By:

**Encounter
info:**

Surgical Pathology Report
MODIFIED-

ICD-3
Adenocarcinoma NOS 8140/3
Site: Prostate NOS C61.9
7/25/14

Surgical Pathology Report

Clinic Number: [REDACTED] **Name:** [REDACTED]

Requested By:

DIAGNOSIS:

A. Right internal/external obturator lymph nodes: Metastatic prostatic adenocarcinoma in one of nine lymph nodes. The lymph node metastasis measures 5 mm in maximum diameter; there is no extranodal extension.

B. Left external iliac lymph nodes: Four lymph nodes negative for carcinoma.

C. Left internal iliac lymph nodes: Metastatic prostatic adenocarcinoma in one of three lymph nodes. The metastasis measures approximately 6 mm in diameter; there is no extranodal extension.

D. Left obturator lymph nodes: Two lymph nodes negative for carcinoma.

E. Prostate.

Procedure: Radical prostatectomy.

Histologic type: Adenocarcinoma of the prostate, acinar type.

Histologic grade:

Primary pattern: 5, Secondary pattern: 5.

Total Gleason Score: 5+5=10.

The patterns here include comedo carcinoma with central necrosis and multiple calcifications, fused glands with loss of acini, and areas showing signet ring cell formation.

Tumor quantitation and location: Carcinoma involves the right and left sides from apex to base with relative sparing of the left base. Each section from the right and left sides shows carcinoma measuring generally in excess of 2 cm in diameter within that block.

Extraprostatic extension: Present. Carcinoma bulges into the pericapsular adipose tissue in several areas: extensively around both seminal vesicles and posteriorly adjacent to the left apex, the left midprostate, and the right midprostate.

Margins: The proximal and distal urethral margins are involved by adenocarcinoma, within distal periurethral prostatic stroma on the right and left sides in over a diameter of 5-6 mm and within the proximal periurethral prostatic stroma and urethral mucosa on the right side in a focus 2 mm in diameter. The apical margins, bladder neck margins, and pericapsular margins are negative for carcinoma.

Lymph-vascular invasion: Present.

Perineural invasion: Present, extensive throughout the carcinoma and in the capsule.

Seminal vesicle invasion: Present. The carcinoma extensively involves the right and left seminal vesicles in foci of extraprostatic carcinoma up to 2 cm in diameter on both sides. The

PRINTED

[page 2 of 4]
right seminal vesicle is largely obliterated by carcinoma.
Treatment effect on carcinoma: Not applicable.
Lymph nodes: Two of eighteen (2/18) lymph nodes are positive for metastatic adenocarcinoma, one in the right internal/external obturator and one in the left internal iliac node groups, with these metastases measuring 5 and 6 mm in diameter, respectively, and showing no extranodal extension (specimens A through D above).
Ancillary studies: DNA ploidy is ordered on block E10 and will be REPORTED IN AN ADDENDUM.
Pathologic staging: pT3b, pN1 (see above for details of nodal involvement).
Biorepository sample (if applicable): Yes, 100% high-grade adenocarcinoma.
Block(s) containing malignancy suitable for additional testing: E8-12.

Interpreted by:

Report electronically signed by
Transcribed by:

ADDENDUM:
Paraffin embedded tumor tissue was sent to _____ for
DNA ploidy by _____ The report
follows:

Source: Prostate, Radical Prostatectomy, Block E10

Results:
The cancer cells are DNA aneuploid.

DIA ploidy test results have been validated by our laboratory for formalin-fixed, paraffin embedded tissue sections. Analysis was performed using the _____ instrument, which determined DNA ploidy status by comparing the DNA content of tumor cells and control cells (selected by _____ operator). This test was developed and its performance characteristics determined by _____. This test has not been cleared or approved by the U.S. Food and Drug Administration.

Proliferation index (MIB-1) = 7.46%.

Ki-67 Antigen immunohistochemical test results have been validated by our laboratory for paraffin embedded tissue sections fixed in formalin. Testing is performed using the MIB-1 clone and a polymer-based detection system. All controls show appropriate reactivity. Image collection and analysis is performed using the _____ instrument. The _____ renders the percentage of positive staining tumor nuclei (tumor selected by operator). This test was developed and its performance characteristics determined by _____. This test has not been cleared or approved by the U.S. Food and Drug Administration.

Transcribed by:

Signed by

PRINTED

[page 3 of 4]
CLINICAL INFORMATION:

Prostate cancer.

SPECIMEN(S):

A:Right internal,external obturator lymph nodes
B:Left external iliac lymph nodes
C:Left internal iliac lymph nodes
D:Left obturator lymph nodes
E:Prostate

A1A2A3A4A5A6B1B2B3B4C1C2D1D2D3E1E2E3E4E5E6E7E8E9E10E11E12E13E14E15E16E17

GROSS DESCRIPTION:

Performed by

A. Received fresh labeled [REDACTED] and "right internal, external obturator lymph nodes" is a 4.5 x 4.5 x 1.5 cm collection of fatty tissue which is sectioned to reveal several rubbery lymph nodes measuring up to 2.7 cm in greatest dimension. The nodal tissue is entirely submitted labeled A1-A5) one bisected lymph node per block; A6) six whole lymph nodes.

B. Received fresh labeled [REDACTED] and "left external iliac lymph nodes" is a 3.0 x 2.5 x 1.0-cm collection of rubbery and fatty tissue which is sectioned to reveal several rubbery lymph nodes measuring up to 1.3 cm in greatest dimension. The nodal tissue is entirely submitted labeled B1-B4) one bisected lymph node per block.

C. Received fresh labeled [REDACTED] "left internal iliac lymph nodes" is a 4.0 x 2.0 x 0.5-cm collection of rubbery and fatty tissue which is sectioned to reveal a few rubbery lymph nodes measuring up to 1.3 cm in greatest dimension. The nodal tissue is entirely submitted labeled C1) one lymph node, bisected; C2) two whole possible lymph nodes.

D. Received fresh labeled [REDACTED] and "left obturator lymph nodes" is a 6.7 x 1.5 x 0.5-cm irregular fragment of rubbery and fatty tissue which is sectioned to reveal two rubbery lymph nodes measuring up to 3.5 cm in greatest dimension. The specimen is entirely submitted labeled D1) one lymph node, trisected; D2-D3) one lymph node, trisected.

E. Received fresh labeled [REDACTED] and "prostate".
Procedure: Radical prostatectomy.

Prostate size: Weight: 64 grams; Dimensions: 5.0 x 4.5 x 4.0 cm;
Seminal vesicles right and left: Approximately 1.5 x 1.5 x 0.5 cm.
Gross notes: Grossly evident tumor: Yes, size approximately 4.5 x 2.0 x 1.5 cm. Location: Extending from apex to base along the posterior aspect of the specimen (right and left).

Symmetry: Symmetrical.

Gross nodular hyperplasia: Moderate.

Gross capsular bulge/defect: None.

Inking: left-black, right-blue

Biorepository sample collected: Yes.

Lymph nodes: No lymph nodes present.

Block key for specimen E:

- 1) proximal urethral margin
- 2) distal urethral margin
- 3) left apical margin, perpendicular
- 4) right apical margin, perpendicular
- 5) left bladder neck margin, perpendicular
- 6) right bladder neck margin, perpendicular
- 7) left apical prostate

PRINTED

[page 4 of 4]
- 8) right apical prostate
- 9) left mid prostate
- 10) right mid prostate
- 11) left mid prostate
- 12) right mid prostate
- 13) left base of prostate
- 14) right base of prostate
- 15) left seminal vesicle
- 16) right seminal vesicle

Additional sections:

- 17) sample corresponding to research

Support for the diagnosis in this case may have included the use of immunohistochemistry tests that were developed and whose performance characteristics were determined by

. They have not been cleared or approved by the U.S. Food and Drug Administration (FDA). The FDA has determined that such clearance or approval is not necessary. These tests should not be regarded as investigational or for research. This laboratory is certified under the Clinical Laboratory Improvement Amendments of 1988 ('CLIA') as qualified to perform high complexity clinical laboratory testing.

CLIA Discrepancy		

Source: NCI Genomic Data Commons file b6d79f85-f399-4d5d-a85d-6f8325e8d76a (TCGA-XK-AAIV.84F5F45E-FE71-407C-A892-996B8A6CC0B6.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).